CCDI case PBCJCW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/afd9b877-ef82-4f17-81b7-2ab22ae80b73

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Diagnosis record without a diagnosis name: ICD-O-3 morphology code: 9473/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (654 days).

Biospecimens (3 samples)
- Sample 0DT3UA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT3UE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DT3US: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
